Gene-level copy-number profile of tumor specimen TCGA-C5-A2M2-01A from TCGA case TCGA-C5-A2M2, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 56.1 years (20,480 days).
Specimen TCGA-C5-A2M2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.cc7bb20a-8a69-48dc-965f-c2f93361c7f4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A2M2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c0301bcb-d6ce-42e4-a2d5-e9d570c174f5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 2,578; copy number 2: 53,467; copy number 3: 2,134; copy number 4: 827; copy number 5: 19; copy number 8: 773.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A2M2-01A-21D-A18H-01): tumor purity 0.92, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:50,795,120–52,339,025, 20 genes: MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.3, AC016383.2, AC016383.1.
- chr18:52,409,042–52,419,644, 2 genes: AC011155.1, VN1R76P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 792 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:143,897,263–145,338,057, 19 genes, copy number 5: Y_RNA, AC016910.1, GTDC1, ZEB2, AC009951.5, AC009951.4, ZEB2-AS1, AC009951.2, AC009951.1, AC009951.3, AC009951.6, LINC01412, TEX41, AC023128.1, AC023128.2, SGCEP1, LINC01966, AC096666.1, RPL6P5.
- chr3:154,651,656–198,222,513, 773 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,576. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
